Somatic mutation profile of tumor specimen TCGA-PC-A5DK-01A (aliquot TCGA-PC-A5DK-01A-11D-A27P-09) from TCGA case TCGA-PC-A5DK, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 63.0 years (23,019 days).
Specimen TCGA-PC-A5DK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc9fa478-3141-45f0-8e8e-28270a6cab1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PC-A5DK-10A (Blood Derived Normal), aliquot TCGA-PC-A5DK-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e2a24f2-3020-46f5-9304-52029ada7d90

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 19/30 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC28A | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236685; called by muse, mutect2, varscan2
- CENPE | c.2377G>C p.G793R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV99479480; called by muse, mutect2, varscan2
- MAP3K11 | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100482802; called by muse, mutect2
- MME | c.1019A>T p.N340I | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1484921016, COSV100852575; called by muse, mutect2, varscan2
- MYO9A | c.6716G>A p.C2239Y | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100614598; called by muse, mutect2, varscan2
- P2RY2 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100232906; called by muse, mutect2, varscan2
- ROCK2 | c.971A>T p.H324L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV99838015; called by muse, mutect2, varscan2
- STT3A | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101205320, COSV67064984; called by muse, mutect2, varscan2
- VIPR1 | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285810; called by muse, mutect2, varscan2
- VN1R2 | c.1113C>G p.D371E | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.557); catalogued as COSV100448238; called by muse, mutect2, varscan2
- ZMYND12 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100999922; called by muse, mutect2, varscan2
- SMTN | c.2649_2651del p.M883del | In Frame Del (DEL) | VAF 34/81 reads (42%) | called by pindel, varscan2
- DPEP1 | c.339G>A p.P113= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs374005684; called by muse, mutect2, varscan2
- PZP | c.3222G>A p.T1074= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV99739977; called by muse, mutect2, varscan2
